Somatic mutation profile of tumor specimen MMRF_2695_1_BM_CD138pos (aliquot MMRF_2695_1_BM_CD138pos_T1_KHS5U_L14420) from MMRF case MMRF_2695, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2695_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47f75a93-d9d1-49af-ad84-37cc355239d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2695_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2695_1_PB_WBC_C2_KHS5U_L14421; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/882f0365-48f1-402d-ad4b-1c1810e3ee16

The open-access MAF lists 205 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 108 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 69, Missense Mutation 65, Intron 23, Silent 22, Nonsense Mutation 6, 5'UTR 5, 5'Flank 4, RNA 4, Splice Region 3, 3'Flank 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MERTK | c.325A>T p.K109* | Nonsense Mutation (SNP) | VAF 83/165 reads (50%) | catalogued as rs786205533; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); catalogued as COSV55595154, COSV55595243; called by muse, mutect2, varscan2
- C1R | c.1916G>A p.R639Q (on ENST00000536053 / NM_001354346.2; = p.R625Q on NM_001733.7) | Missense Mutation (SNP) | VAF 221/481 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs745821919, COSV101605622; called by muse, mutect2, varscan2
- DACT1 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 46/56 reads (82%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs748458975, COSV60019784; called by muse, mutect2, varscan2
- DLG5 | c.1294T>C p.Y432H | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV64950333; called by muse, mutect2, varscan2
- EEPD1 | c.967A>T p.I323F | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1562711540; called by muse, mutect2, varscan2
- ESRP1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1162356116, COSV64410496; called by muse, mutect2
- HEG1 | c.641G>T p.S214I | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.928); catalogued as rs753943251; called by muse, mutect2, varscan2
- HIP1R | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs1189427074; called by muse, mutect2, varscan2
- HNRNPA1 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52937907; called by muse, mutect2
- MAPKAPK2 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as rs1245550536; called by muse, mutect2
- MOGAT1 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs778019570, COSV71479929; called by muse, mutect2, varscan2
- MOV10L1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs760413650, COSV53171565; called by muse, varscan2
- MROH8 | c.1908C>G p.I636M | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV54125591; called by muse, varscan2
- NHSL1 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs1252410422; called by muse, mutect2, varscan2
- NR0B1 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV66763551; called by muse, mutect2, varscan2
- NR2E3 | c.750G>A p.V250= | Splice Region (SNP) | VAF 22/82 reads (27%) | catalogued as COSV58907081; called by muse, mutect2, varscan2
- NRXN1 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100456105, COSV58459667; called by muse, mutect2, varscan2
- OR11H6 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.379); catalogued as COSV59644312, COSV59644901; called by muse, mutect2
- PPIL2 | c.267C>G p.I89M | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs957559585; called by muse, mutect2, varscan2
- PPP3CB | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55019335; called by muse, mutect2
- PREX2 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs769067107, COSV55781600; called by muse, mutect2, varscan2
- PTPRZ1 | c.3031G>C p.D1011H | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101100799; called by muse, mutect2, varscan2
- PYDC1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1291557204, COSV57250646, COSV57252095; called by muse, mutect2, varscan2
- ROM1 | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); catalogued as rs201291804, COSV53884255; called by muse, mutect2, varscan2
- SPTBN4 | c.1870G>A p.G624S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.089); catalogued as rs868200942; called by muse, mutect2, varscan2
- UPF1 | c.1201G>A p.E401K (on ENST00000599848 / NM_001297549.2; = p.E390K on NM_002911.4) | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV53199015, COSV53200443, COSV99439268; called by muse, mutect2
- WDR62 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 297/522 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV54335099; called by muse, mutect2, varscan2
- AMBRA1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANPEP | c.1836C>A p.F612L | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2
- AP3B1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- APBB1 | c.1504-3C>T | Splice Region (SNP) | VAF 17/261 reads (7%) | called by muse, mutect2
- ARFGEF3 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2
- ARFGEF3 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2
- ARVCF | c.1996C>T p.L666F | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- C22orf42 | c.468A>T p.E156D | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- C2CD3 | c.5533G>C p.E1845Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CD53 | c.533T>A p.F178Y | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CEACAM8 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ELMO2 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ELOB | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ENKD1 | c.843G>T p.E281D | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FAM110B | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FBXO4 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- GGA2 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- GNAS | c.26C>A p.T9N | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GTPBP10 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- IGHV1-69D | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- INPP4A | c.2552G>A p.S851N (on ENST00000074304 / NM_001134224.1; = p.S812N on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA0586 | c.1163C>T p.S388L (on ENST00000619416 / NM_001244190.2; = p.S403L on NM_014749.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KMT2D | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.112); called by muse, mutect2
- LAMB3 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LRRN3 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAF | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- MAP3K8 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- MLC1 | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- MPP7 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- NCR1 | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PEX14 | c.678G>A p.R226= | Splice Region (SNP) | VAF 129/267 reads (48%) | called by muse, mutect2, varscan2
- PRMT9 | c.628A>T p.K210* | Nonsense Mutation (SNP) | VAF 95/222 reads (43%) | called by muse, mutect2, varscan2
- QSER1 | c.2530G>A p.E844K (on ENST00000399302; = p.E973K on NM_001076786.3) | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- SALL4 | c.2246G>A p.R749K | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- SIX4 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- SLC24A1 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- SLC37A3 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2
- SLC4A8 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TAF1B | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- TATDN2 | c.293C>G p.S98C | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TENT5C | c.98T>A p.V33E | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TRAPPC11 | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- TRIM73 | c.-18-1G>A | Splice Site (SNP) | VAF 26/190 reads (14%) | called by muse, mutect2, varscan2
- TSPAN16 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2
- UACA | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR62 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 109/191 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- WDR62 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCC2 | c.2724C>T p.S908= | Silent (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- APOLD1 | c.297C>T p.L99= (on ENST00000326765 / NM_001130415.2; = p.L68= on NM_030817.3) | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1399735598; called by muse, mutect2, varscan2
- ATR | c.2740C>T p.L914= | Silent (SNP) | VAF 51/157 reads (32%) | called by muse, mutect2, varscan2
- CCDC168 | c.18363G>A p.K6121= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs1177225962; called by muse, mutect2, varscan2
- CNTN3 | c.1269G>A p.V423= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV55180179; called by muse, mutect2, varscan2
- FAM83H | c.2085C>T p.G695= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as rs1554622535; called by muse, mutect2, varscan2
- FBXO5 | c.303G>A p.V101= | Silent (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- FCER2 | c.777C>T p.C259= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs1036781021; called by muse, mutect2, varscan2
- ITGAE | c.354C>T p.L118= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- KASH5 | c.1032G>A p.L344= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- KIF1C | c.2028C>T p.S676= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs758660608; called by muse, mutect2, varscan2
- LASP1 | c.147G>A p.K49= | Silent (SNP) | VAF 30/224 reads (13%) | called by muse, mutect2, varscan2
- MAD2L1 | c.33C>T p.I11= | Silent (SNP) | VAF 22/218 reads (10%) | called by muse, mutect2
- MROH8 | c.1992C>A p.L664= | Silent (SNP) | VAF 68/80 reads (85%) | called by muse, varscan2
- NOS2 | c.2958C>T p.I986= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs1281093350, COSV58225672; called by muse, mutect2, varscan2
- OR13C5 | c.531C>T p.F177= | Silent (SNP) | VAF 18/523 reads (3%) | catalogued as COSV66165252; called by muse, mutect2
- OR4D1 | c.432G>T p.L144= | Silent (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- PUF60 | c.1671C>G p.L557= (on ENST00000526683 / NM_001362896.2; = p.L540= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 62/283 reads (22%) | called by muse, mutect2, varscan2
- TBX4 | c.594C>A p.I198= | Silent (SNP) | VAF 50/213 reads (23%) | called by muse, mutect2, varscan2
- TRANK1 | c.3828C>T p.Y1276= | Silent (SNP) | VAF 80/208 reads (38%) | catalogued as rs777420821, COSV57166982; called by muse, mutect2, varscan2
- VKORC1 | c.39C>G p.L13= | Silent (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- ZMIZ1 | c.1578C>T p.I526= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as rs776816949; called by muse, mutect2, varscan2
- AC012236.1 | n.160T>A | RNA (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- ADGRL3 | c.*12G>A | 3'UTR (SNP) | VAF 106/247 reads (43%) | catalogued as rs534180291; called by muse, mutect2, varscan2
- ALG10B | c.*157G>A | 3'UTR (SNP) | VAF 7/64 reads (11%) | catalogued as rs566875904; called by muse, mutect2
- ALG10B | c.*236G>A | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ALG10B | c.*480G>A | 3'UTR (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- ALG10B | c.*662T>A | 3'UTR (SNP) | VAF 27/254 reads (11%) | called by muse, varscan2
- ALG10B | c.*2667C>T | 3'UTR (SNP) | VAF 24/204 reads (12%) | catalogued as rs1288348673; called by muse, varscan2
- ALG10B | c.*2708C>T | 3'UTR (SNP) | VAF 34/334 reads (10%) | called by muse, varscan2
- ALG10B | c.*2813C>T | 3'UTR (SNP) | VAF 35/328 reads (11%) | called by muse, varscan2
- ALG10B | c.*2893C>T | 3'UTR (SNP) | VAF 6/61 reads (10%) | catalogued as rs1229217654; called by muse, mutect2, varscan2
- ALPI | c.*582C>T | 3'UTR (SNP) | VAF 16/207 reads (8%) | called by muse, mutect2
- ATXN3 | c.*1241C>T | 3'UTR (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- BCL7A | chr12:122021301 T>G | 5'Flank (SNP) | VAF 58/101 reads (57%) | catalogued as COSV55851783; called by muse, varscan2
- BCL7A | chr12:122021361 G>C | 5'Flank (SNP) | VAF 44/124 reads (35%) | catalogued as COSV55849380; called by muse, varscan2
- BIVM-ERCC5 | c.3317-118C>T | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- C22orf39 | c.*3097G>A | 3'UTR (SNP) | VAF 65/148 reads (44%) | called by muse, mutect2, varscan2
- C8orf33 | c.318+22G>T | Intron (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- CACNB4 | c.*6330A>C | 3'UTR (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- CAMK2G | c.-70C>T | 5'UTR (SNP) | VAF 9/47 reads (19%) | catalogued as rs1230752926; called by muse, mutect2, varscan2
- CAV1 | c.*1263G>C | 3'UTR (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- CBR4 | c.*1316T>C | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by mutect2, varscan2
- CCDC126 | c.-31C>T | 5'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- CCDC28B | c.164+203C>T | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- CCDC30 | c.2270+61G>A | Intron (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- CCDC88C | c.*14G>T | 3'UTR (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- CEACAM1 | c.-18G>A | 5'UTR (SNP) | VAF 71/231 reads (31%) | called by muse, varscan2
- CHUK | c.*1244C>T | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- CMC1 | c.19+37C>T | Intron (SNP) | VAF 38/119 reads (32%) | catalogued as rs1465358866, COSV58362375; called by muse, mutect2, varscan2
- COL5A1 | c.*968C>T | 3'UTR (SNP) | VAF 26/88 reads (30%) | catalogued as rs1465825585; called by muse, mutect2, varscan2
- CX3CR1 | c.*963G>C | 3'UTR (SNP) | VAF 8/145 reads (6%) | called by muse, mutect2
- CX3CR1 | c.*662G>C | 3'UTR (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- CXCL16 | c.*6G>C | 3'UTR (SNP) | VAF 32/392 reads (8%) | catalogued as rs781441495; called by muse, mutect2
- DAG1 | c.*2308C>T | 3'UTR (SNP) | VAF 7/51 reads (14%) | catalogued as rs1329290515; called by muse, mutect2, varscan2
- DNAJB14 | c.*3723G>A | 3'UTR (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- DNAJC6 | c.*194G>A | 3'UTR (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2
- DNM1P33 | n.25T>C | RNA (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- EFCAB1 | c.-1C>T | 5'UTR (SNP) | VAF 42/87 reads (48%) | catalogued as rs1185786292; called by muse, mutect2, varscan2
- ERLIN1 | chr10:100151498 G>C | 3'Flank (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- FBXO3 | c.1239+798C>T | Intron (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- FCHSD2 | c.-7C>T | 5'UTR (SNP) | VAF 100/225 reads (44%) | called by muse, mutect2, varscan2
- GLIPR1 | c.*2310C>G | 3'UTR (SNP) | VAF 25/54 reads (46%) | catalogued as rs1326705846; called by muse, mutect2, varscan2
- HDAC4 | c.*4352C>T | 3'UTR (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- HMG20B | c.520-79C>T | Intron (SNP) | VAF 22/84 reads (26%) | catalogued as rs992998800; called by muse, mutect2, varscan2
- HOXA10 | c.*384G>A | 3'UTR (SNP) | VAF 9/241 reads (4%) | catalogued as rs1042799233; called by muse, mutect2
- HOXA4 | chr7:27128522 T>G | 3'Flank (SNP) | VAF 24/35 reads (69%) | called by muse, mutect2, varscan2
- HSPB8 | c.*127T>C | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- IKBKE | chr1:206497706 G>A | 3'Flank (SNP) | VAF 62/206 reads (30%) | catalogued as rs1553392519; called by muse, mutect2, varscan2
- INAVA | c.*103G>A | 3'UTR (SNP) | VAF 17/211 reads (8%) | catalogued as rs1256695989; called by muse, mutect2
- INKA2 | c.*1876C>T | 3'UTR (SNP) | VAF 40/66 reads (61%) | called by muse, mutect2, varscan2
- ITGAX | c.*65C>G | 3'UTR (SNP) | VAF 7/197 reads (4%) | called by muse, mutect2
- LRP8 | c.*1012G>C | 3'UTR (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- MAML2 | c.*1990C>G | 3'UTR (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- MBD3 | c.*3192C>T | 3'UTR (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
- MEGF9 | c.*3634T>G | 3'UTR (SNP) | VAF 27/156 reads (17%) | called by muse, mutect2, varscan2
- MMP11 | c.1075+67G>A | Intron (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- MSMO1 | c.*747G>A | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- MYOZ2 | c.*520C>T | 3'UTR (SNP) | VAF 24/46 reads (52%) | catalogued as rs1294751659; called by muse, mutect2, varscan2
- NBL1 | c.*1173C>G | 3'UTR (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- NELFB | c.*542C>T | 3'UTR (SNP) | VAF 29/112 reads (26%) | called by muse, mutect2, varscan2
- NFIB | chr9:14314389 G>A | 5'Flank (SNP) | VAF 10/88 reads (11%) | called by mutect2, varscan2
- NFS1 | c.*403C>A | 3'UTR (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- NIPSNAP2 | c.*265C>T | 3'UTR (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- NLN | c.*3363G>C | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- NT5E | c.*448G>A | 3'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- NUDT12 | c.*1179T>C | 3'UTR (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- NUDT16 | c.*1291G>A | 3'UTR (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- PAX5 | c.*72G>A | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- PCDH7 | c.*383T>G | 3'UTR (SNP) | VAF 25/60 reads (42%) | catalogued as rs1405668904; called by muse, mutect2, varscan2
- PCNX2 | c.4077-483C>T | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- PCP4L1 | c.*431C>T | 3'UTR (SNP) | VAF 19/195 reads (10%) | called by muse, mutect2
- PCSK5 | c.*329A>T | 3'UTR (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- PDCD1LG2 | c.*695G>T | 3'UTR (SNP) | VAF 13/40 reads (33%) | catalogued as rs199621794; called by muse, mutect2, varscan2
- POU6F1 | c.*539C>T | 3'UTR (SNP) | VAF 29/135 reads (21%) | called by muse, mutect2, varscan2
- PPP2R1B | c.*2377G>A | 3'UTR (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- PPP2R2B | c.1052+842G>A | Intron (SNP) | VAF 19/231 reads (8%) | called by muse, mutect2
- PPP3R1 | chr2:68253178 G>C | 5'Flank (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- PRDM16 | c.*3151del | 3'UTR (DEL) | VAF 128/312 reads (41%) | called by mutect2, pindel, varscan2
- PRSS16 | c.1150+460C>T | Intron (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- PTP4A1 | c.*24G>A | 3'UTR (SNP) | VAF 63/166 reads (38%) | called by muse, mutect2, varscan2
- RFX2 | c.1134+52G>A | Intron (SNP) | VAF 32/86 reads (37%) | catalogued as rs1196620294; called by muse, mutect2, varscan2
- RUSC1 | c.1534-20C>T | Intron (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2
- S1PR2 | c.-43+749G>A | Intron (SNP) | VAF 49/166 reads (30%) | called by muse, mutect2, varscan2
- SHH | c.*640A>G | 3'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- SLAMF1 | c.*462G>T | 3'UTR (SNP) | VAF 61/389 reads (16%) | catalogued as rs1369274490; called by muse, mutect2, varscan2
- SOAT1 | c.*3142C>T | 3'UTR (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- SOX11 | c.*5975C>T | 3'UTR (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- SP6 | c.*320G>T | 3'UTR (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- SPSB2 | c.664+432C>A | Intron (SNP) | VAF 53/121 reads (44%) | called by muse, varscan2
- SRPRB | c.-173-103C>T | Intron (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- STUM | c.*2559G>A | 3'UTR (SNP) | VAF 51/159 reads (32%) | called by muse, mutect2, varscan2
- STX18 | c.*714G>A | 3'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- TBX3 | c.718-86G>A | Intron (SNP) | VAF 3/31 reads (10%) | catalogued as rs974564979; called by muse, mutect2
- TCF12 | c.1115-61C>T | Intron (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- TIA1 | c.*2207C>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- TMEFF2 | c.439+2804A>G | Intron (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- TMEM167A | c.*3193G>C | 3'UTR (SNP) | VAF 26/228 reads (11%) | called by muse, mutect2, varscan2
- TMEM30B | c.*2559C>T | 3'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- TMEM38B | c.*1354C>T | 3'UTR (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- TMEM50B | c.99+72G>A | Intron (SNP) | VAF 19/278 reads (7%) | called by muse, mutect2
- TMPRSS11A | c.*848G>A | 3'UTR (SNP) | VAF 9/60 reads (15%) | catalogued as rs568282181; called by muse, mutect2, varscan2
- TNC | c.4580-4244G>A | Intron (SNP) | VAF 6/62 reads (10%) | catalogued as rs940865051; called by muse, mutect2, varscan2
- TNRC18P3 | n.1416C>T | RNA (SNP) | VAF 2/24 reads (8%) | catalogued as rs868959128; called by muse, mutect2
- TPH1 | c.*2109T>C | 3'UTR (SNP) | VAF 14/33 reads (42%) | catalogued as rs952338166; called by muse, mutect2, varscan2
- UNC5D | c.*1215C>A | 3'UTR (SNP) | VAF 66/116 reads (57%) | called by muse, mutect2, varscan2
- USP49 | c.1876+628C>T | Intron (SNP) | VAF 6/13 reads (46%) | catalogued as rs1011449649; called by muse, mutect2
- VSTM2A | c.634+1745G>A | Intron (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- ZNF725P | n.1079G>A | RNA (SNP) | VAF 51/172 reads (30%) | called by muse, mutect2, varscan2
- ZNF770 | c.*2877G>A | 3'UTR (SNP) | VAF 30/142 reads (21%) | called by muse, mutect2, varscan2
